Somatic mutation profile of tumor specimen TCGA-BA-5149-01A (aliquot TCGA-BA-5149-01A-01D-1512-08) from TCGA case TCGA-BA-5149, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 47.0 years (17,177 days).
Specimen TCGA-BA-5149-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6da40662-df5f-48ac-a41c-1db1a883dba6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-5149-10A (Blood Derived Normal), aliquot TCGA-BA-5149-10A-01D-1512-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa2be04a-e518-4cb8-8cfe-fd16879d560d

The open-access MAF lists 122 somatic variants for this specimen: 99 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 20, Nonsense Mutation 5, Frame Shift Del 5, In Frame Ins 1, Intron 1, 3'UTR 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 45/127 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- UGDH | c.41A>G p.Y14C | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369608407; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.4258G>A p.D1420N | Missense Mutation (SNP) | VAF 49/229 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV100588615; called by muse, mutect2, varscan2
- ABHD5 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.019); catalogued as rs764177895, COSV50006510; called by muse, mutect2, varscan2
- ADAM8 | c.1695C>G p.I565M | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV101291654; called by muse, mutect2, varscan2
- ADCY1 | c.2950G>T p.V984L | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99811826; called by muse, mutect2, varscan2
- ADCY6 | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as rs746195042, COSV57168003; called by muse, mutect2, varscan2
- ANK2 | c.11743A>C p.K3915Q | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.756); catalogued as COSV100001083; called by muse, mutect2, varscan2
- ANKRD11 | c.1742C>G p.S581C | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56369831, COSV99969038; called by muse, mutect2, varscan2
- ARRDC2 | c.984G>T p.R328S | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV99716712; called by muse, mutect2
- ASB9 | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 40/101 reads (40%) | catalogued as COSV100995469; called by muse, mutect2, varscan2
- ASIC2 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758581731, COSV63320840; called by muse, mutect2, varscan2
- ATF6B | c.376A>T p.T126S | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100913556; called by muse, mutect2, varscan2
- ATP2B1 | c.3112A>T p.I1038L | Missense Mutation (SNP) | VAF 66/286 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53812845, COSV99665516; called by muse, mutect2, varscan2
- ATRNL1 | c.2741G>A p.R914Q | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.994); catalogued as rs1554924686, COSV58114600; called by muse, mutect2, varscan2
- CAMKK2 | c.1405G>C p.E469Q | Missense Mutation (SNP) | VAF 37/255 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100242848; called by muse, mutect2, varscan2
- CETP | c.151G>T p.A51S | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.322); catalogued as rs549487844, COSV99569986, COSV99570357; called by muse, mutect2, varscan2
- CFAP206 | c.1070A>G p.H357R | Missense Mutation (SNP) | VAF 86/225 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.245); catalogued as COSV99739403; called by muse, mutect2, varscan2
- CILP | c.1137G>C p.Q379H | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.184); catalogued as COSV99973240; called by muse, mutect2, varscan2
- COX15 | c.787T>C p.F263L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV99186993; called by muse, mutect2, varscan2
- CRMP1 | c.259G>C p.D87H | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100271743; called by muse, mutect2, varscan2
- CRYGS | c.49C>G p.Q17E | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.21); catalogued as COSV100329954, COSV100329970; called by muse, mutect2, varscan2
- CTH | c.196C>G p.P66A | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as COSV100697068, COSV61008513; called by muse, mutect2, varscan2
- CYP11B2 | c.465G>C p.Q155H | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV100010951; called by muse, mutect2, varscan2
- CYP46A1 | c.1010G>A p.G337D | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767699278, COSV99952580; called by muse, mutect2, varscan2
- DAGLA | c.1244A>T p.E415V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99944287; called by muse, mutect2, varscan2
- DNAH5 | c.12037C>T p.R4013C | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs148349630; called by muse, mutect2, varscan2
- DOCK5 | c.1084C>G p.L362V | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.184); catalogued as COSV99376724; called by muse, mutect2, varscan2
- DPP4 | c.2227G>A p.A743T | Missense Mutation (SNP) | VAF 55/268 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV100858827; called by muse, mutect2, varscan2
- EPDR1 | c.491T>A p.I164N | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99554368; called by muse, mutect2
- EPS8L2 | c.261C>G p.I87M | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs554819887, COSV100585487; called by muse, mutect2, varscan2
- FAM111B | c.1201C>G p.Q401E | Missense Mutation (SNP) | VAF 53/187 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100639271; called by muse, mutect2, varscan2
- FAM120B | c.336A>G p.I112M | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV99379253; called by muse, mutect2, varscan2
- FAM227B | c.169A>G p.I57V | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as COSV100174843, COSV100175622; called by muse, mutect2, varscan2
- FAT2 | c.5514C>A p.F1838L | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as rs1376431808, COSV99942524; called by muse, mutect2, varscan2
- FAT3 | c.5425G>A p.A1809T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99965059; called by muse, mutect2, varscan2
- FAT3 | c.5426C>A p.A1809D | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99965060; called by muse, mutect2, varscan2
- GABRP | c.248C>A p.T83K | Missense Mutation (SNP) | VAF 16/389 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99516721; called by muse, mutect2
- GAS7 | c.1395G>C p.K465N (on ENST00000432992 / NM_201433.2; = p.K325N on NM_003644.3) | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs967868961, COSV100095226; called by muse, mutect2, varscan2
- GPD2 | c.1495G>C p.A499P | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.086); catalogued as COSV100133174, COSV60090002; called by muse, mutect2, varscan2
- GPI | c.292G>T p.V98L | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV100731498; called by muse, mutect2, varscan2
- GPR22 | c.734G>A p.R245K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.355); catalogued as COSV99771895; called by muse, mutect2, varscan2
- H2AC1 | c.298G>A p.G100S | Missense Mutation (SNP) | VAF 131/365 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.118); catalogued as rs775985152, COSV99219384; called by muse, mutect2, varscan2
- HEATR4 | c.1924C>A p.Q642K | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as rs1394192526, COSV100620315; called by muse, mutect2, varscan2
- HEATR4 | c.1923T>A p.C641* | Nonsense Mutation (SNP) | VAF 36/236 reads (15%) | catalogued as COSV100620316; called by muse, mutect2, varscan2
- HESX1 | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 134/514 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs149663188; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IRAK1 | c.1879G>A p.G627R | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV100888984; called by muse, mutect2, varscan2
- KCNB2 | c.520G>C p.D174H | Missense Mutation (SNP) | VAF 42/273 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV101578744, COSV73050926; called by muse, mutect2, varscan2
- KMT2D | c.7448C>G p.S2483C | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV99980445; called by muse, mutect2, varscan2
- KYAT3 | c.590C>G p.P197R | Missense Mutation (SNP) | VAF 41/255 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.731); catalogued as COSV99556054; called by muse, mutect2, varscan2
- LTBP1 | c.2966G>C p.R989P (on ENST00000404816 / NM_206943.4; = p.R663P on NM_000627.4) | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.596); catalogued as COSV100616468, COSV100616933; called by muse, mutect2, varscan2
- MAP3K1 | c.1757G>A p.R586H | Missense Mutation (SNP) | VAF 50/347 reads (14%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.928); catalogued as rs748356370, COSV68127333; called by muse, mutect2, varscan2
- MAPKBP1 | c.2567G>A p.R856H (on ENST00000456763 / NM_001128608.2; = p.R850H on NM_014994.3) | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761535097, COSV99529274; called by muse, mutect2, varscan2
- MC2R | c.271T>A p.Y91N | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.723); catalogued as COSV100562974; called by muse, varscan2
- MTSS1 | c.736G>C p.D246H | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100274747; called by muse, mutect2, varscan2
- MTUS2 | c.632G>T p.G211V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as COSV101462171; called by muse, mutect2, varscan2
- MYF5 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV57354247; called by muse, mutect2, varscan2
- NOM1 | c.1834G>T p.V612L | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.349); catalogued as COSV99315632; called by muse, mutect2, varscan2
- NR1I2 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as rs201179068, COSV61978948; called by muse, mutect2, varscan2
- NRG3 | c.542C>A p.S181Y | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV64580681; called by muse, mutect2, varscan2
- OPRPN | c.398T>C p.I133T | Missense Mutation (SNP) | VAF 60/285 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV101271084; called by muse, mutect2, varscan2
- OR4N2 | c.540T>A p.D180E | Missense Mutation (SNP) | VAF 97/264 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100269557; called by muse, mutect2, varscan2
- PCLO | c.2411A>C p.Q804P | Missense Mutation (SNP) | VAF 88/286 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); catalogued as COSV100431155, COSV61636021; called by muse, mutect2, varscan2
- PPFIA2 | c.2659G>T p.E887* | Nonsense Mutation (SNP) | VAF 3/19 reads (16%) | catalogued as COSV100332887, COSV100336036; called by muse, mutect2
- PRKAB1 | c.329A>G p.N110S | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.065); catalogued as COSV57555514, COSV99982356; called by muse, mutect2, varscan2
- PRR16 | c.266C>A p.A89D (on ENST00000407149 / NM_001300783.2; = p.A66D on NM_016644.2) | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101086893; called by muse, mutect2, varscan2
- RBL1 | c.284A>C p.K95T | Missense Mutation (SNP) | VAF 71/190 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV100726998; called by muse, mutect2, varscan2
- RBM25 | c.791T>G p.I264R | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV99998626; called by muse, mutect2, varscan2
- RELN | c.2831T>A p.M944K | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.78); PolyPhen benign (0.091); catalogued as COSV100633414; called by muse, mutect2, varscan2
- RETREG3 | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 36/56 reads (64%) | catalogued as COSV52220697; called by muse, mutect2, varscan2
- RGS9 | c.353A>G p.D118G | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99287370; called by muse, mutect2, varscan2
- RHOG | c.566T>G p.I189S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.005); catalogued as COSV99544218; called by muse, mutect2, varscan2
- S100PBP | c.995A>C p.H332P | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV100758346; called by muse, mutect2, varscan2
- SEPTIN12 | c.334G>C p.D112H | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51619377, COSV99190588; called by muse, mutect2, varscan2
- SLAIN1 | c.1100C>T p.S367F (on ENST00000466548; = p.S104F on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/161 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as rs763028775, COSV99935120; called by muse, mutect2, varscan2
- SLC16A10 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772294671, COSV100920791; called by muse, mutect2, varscan2
- SLC4A7 | c.211A>T p.R71* | Nonsense Mutation (SNP) | VAF 84/166 reads (51%) | catalogued as COSV99839608; called by muse, mutect2, varscan2
- SLC7A3 | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs956697533, COSV99979497; called by muse, mutect2, varscan2
- SLC8A1 | c.269T>G p.L90R | Missense Mutation (SNP) | VAF 89/210 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100245646, COSV60479390; called by muse, mutect2, varscan2
- SLCO5A1 | c.1881G>C p.K627N | Missense Mutation (SNP) | VAF 53/314 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.846); catalogued as COSV99479799; called by muse, mutect2, varscan2
- SMG1 | c.6625G>T p.D2209Y | Missense Mutation (SNP) | VAF 51/242 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101245718; called by muse, mutect2, varscan2
- SVIL | c.1501C>G p.Q501E | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs772337197, COSV100881213; called by muse, mutect2, varscan2
- TKTL2 | c.1350C>G p.F450L | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.487); catalogued as COSV54917401, COSV54922345, COSV99761327; called by muse, mutect2, varscan2
- TMEM38B | c.406T>A p.Y136N | Missense Mutation (SNP) | VAF 88/139 reads (63%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV101016280; called by muse, mutect2, varscan2
- TNRC6B | c.5470G>A p.D1824N (on ENST00000454349 / NM_001162501.2; = p.D1714N on NM_015088.3) | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as COSV100109514; called by muse, mutect2, varscan2
- TNXB | c.5862G>T p.Q1954H (on ENST00000647633; = p.Q1707H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1338190417, COSV100926209; called by muse, mutect2, varscan2
- TP53RK | c.335A>G p.Y112C | Missense Mutation (SNP) | VAF 115/637 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs1292100340, COSV100927750; called by muse, mutect2, varscan2
- TRAM1L1 | c.970G>T p.V324L | Missense Mutation (SNP) | VAF 151/375 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100162152; called by muse, mutect2, varscan2
- TRIM27 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101019288; called by muse, mutect2, varscan2
- WLS | c.1084A>C p.T362P | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.287); catalogued as COSV99259434; called by muse, mutect2, varscan2
- ZFPM1 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs768527783, COSV100128364; called by muse, mutect2, varscan2
- ZNF337 | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs575478110, COSV99430144; called by muse, mutect2, varscan2
- CEP57L1 | c.1368_1370del p.I456del | In Frame Del (DEL) | VAF 16/70 reads (23%) | called by mutect2, pindel, varscan2
- KIAA1549L | c.1011_1017del p.T338Lfs*33 (on ENST00000321505; = p.T635Lfs*33 on NM_012194.3) | Frame Shift Del (DEL) | VAF 37/286 reads (13%) | called by mutect2, pindel, varscan2
- NOTCH1 | c.1539_1545del p.Q513Hfs*116 | Frame Shift Del (DEL) | VAF 12/23 reads (52%) | called by mutect2, varscan2
- OGDH | c.1076del p.N359Ifs*26 | Frame Shift Del (DEL) | VAF 62/275 reads (23%) | called by mutect2, pindel, varscan2
- POLR3H | c.239del p.F80Sfs*2 | Frame Shift Del (DEL) | VAF 25/100 reads (25%) | called by mutect2, pindel, varscan2
- STK16 | c.888_890dup p.A297dup | In Frame Ins (INS) | VAF 19/151 reads (13%) | called by mutect2, pindel, varscan2
- WFIKKN1 | c.188del p.E63Gfs*155 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel
- APOB | c.11025C>A p.I3675= | Silent (SNP) | VAF 59/152 reads (39%) | catalogued as COSV51940893, COSV51946158; called by muse, mutect2, varscan2
- CBFA2T2 | c.885C>T p.T295= | Silent (SNP) | VAF 49/134 reads (37%) | catalogued as rs755250770, COSV100656286; called by muse, mutect2, varscan2
- COL6A6 | c.3135C>T p.S1045= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as rs539153024, COSV62027163; called by muse, mutect2, varscan2
- DMXL1 | c.2181G>A p.R727= | Silent (SNP) | VAF 27/324 reads (8%) | catalogued as rs547579179, COSV100223787; called by muse, mutect2
- GRM3 | c.570C>T p.T190= | Silent (SNP) | VAF 43/211 reads (20%) | catalogued as rs754123274, COSV64469532, COSV64473417; called by muse, mutect2, varscan2
- HTR1D | c.138C>T p.S46= | Silent (SNP) | VAF 100/215 reads (47%) | catalogued as rs747145800, COSV100024819; called by muse, mutect2, varscan2
- IFT57 | c.102C>A p.P34= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as COSV99197411; called by muse, mutect2, varscan2
- IGFBP3 | c.531A>G p.K177= | Silent (SNP) | VAF 127/295 reads (43%) | catalogued as COSV99298311; called by muse, mutect2, varscan2
- IGHD5-12 | c.18G>A p.T6= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs782319887; called by muse, mutect2, varscan2
- MARK4 | c.447G>A p.S149= | Silent (SNP) | VAF 16/194 reads (8%) | catalogued as rs772689017, COSV53462455; called by muse, mutect2
- NAV1 | c.2070A>T p.G690= | Silent (SNP) | VAF 48/102 reads (47%) | catalogued as COSV99818662; called by muse, mutect2, varscan2
- RALGAPB | c.991C>T p.L331= | Silent (SNP) | VAF 58/517 reads (11%) | catalogued as COSV99485089; called by muse, mutect2, varscan2
- RUNX1 | c.585C>T p.S195= (on ENST00000344691 / NM_001001890.3; = p.S222= on NM_001754.5) | Silent (SNP) | VAF 28/170 reads (16%) | catalogued as rs747906151, COSV55876685; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC7A3 | c.120G>T p.L40= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV99979501; called by muse, mutect2, varscan2
- SLCO4C1 | c.750A>T p.G250= | Silent (SNP) | VAF 10/129 reads (8%) | catalogued as COSV100194823; called by muse, mutect2
- STAG2 | c.147C>T p.G49= | Silent (SNP) | VAF 77/109 reads (71%) | catalogued as COSV99493131; called by muse, mutect2, varscan2
- TMIGD1 | c.732G>A p.K244= | Silent (SNP) | VAF 28/138 reads (20%) | catalogued as COSV100187205, COSV61028010; called by muse, varscan2
- TRPC4 | c.591C>G p.L197= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as COSV100156589; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1614C>G p.L538= | Silent (SNP) | VAF 42/189 reads (22%) | catalogued as COSV99837586; called by muse, mutect2, varscan2
- ZNF567 | c.1371C>A p.S457= (on ENST00000536254 / NM_001322913.1; = p.S426= on NM_152603.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 39/118 reads (33%) | catalogued as COSV100658760; called by muse, mutect2, varscan2
- ATRIP | c.*1039_*1040del | 3'UTR (DEL) | VAF 85/246 reads (35%) | called by mutect2, pindel, varscan2
- DCHS2 | n.7605G>T | RNA (SNP) | VAF 17/118 reads (14%) | catalogued as COSV100601609, COSV61768891; called by muse, mutect2, varscan2
- RBM44 | c.-98-2143C>G | Intron (SNP) | VAF 33/147 reads (22%) | catalogued as rs1193873040, COSV100389779; called by muse, mutect2, varscan2
